Gene-level copy-number profile of tumor specimen TCGA-CG-4469-01A from TCGA case TCGA-CG-4469, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 70.1 years (25,598 days).
Specimen TCGA-CG-4469-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.7a7b6ff0-496a-48cc-a302-eb258aaf5b15.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4469-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/20ea4417-5854-4bb3-a7b5-dcfe7a9e6c09

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 5,779; copy number 2: 44,641; copy number 3: 9,350; copy number 6: 1; copy number 10: 2; copy number 11: 4; copy number 20: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4469-01A-01D-1155-01): tumor purity 0.82, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.
- chr6:164,791,288–164,832,114, 2 genes: AL450345.2, AL450345.1.
- chr16:78,166,717–78,241,989, 2 genes: AC009044.1, WWOX-AS1.
- chr16:78,495,926–78,526,535, 2 genes: AC046158.1, AC046158.4.
- chr16:78,981,722–79,110,882, 6 genes: AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,253,213–127,257,630, 1 gene, copy number 6: AC018714.2.
- chr10:120,925,547–121,185,966, 4 genes, copy number 11: AC010998.1, AC010998.3, RPL19P16, LINC01153.
- chr10:121,478,332–121,615,839, 2 genes, copy number 10 (within-gene range 1–10): FGFR2, AC009988.1.

Autosomal genes at a single copy (total copy number 1): 4,538. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
